Somatic mutation profile of tumor specimen 0DV4J1 from CCDI case PBCMGZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Temporal lobe; Age at diagnosis: 16.8 years (6,152 days).
Specimen 0DV4J1: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1f323905-ac65-43a7-be69-69cad98d2bfb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DV4IU (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7a13afde-cc25-47af-be99-ce537e5de30a

The open-access MAF lists 17 somatic variants for this specimen: 10 protein-altering or splice-affecting, 2 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Intron 5, Silent 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 647/1685 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- SYNE1 | c.12869A>G p.Y4290C (on ENST00000367255 / NM_182961.4; = p.Y4219C on NM_033071.3) | Missense Mutation (SNP) | VAF 90/1882 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs1163302129; called by muse, mutect2
- TCL1B | c.190T>C p.W64R | Missense Mutation (SNP) | VAF 19/511 reads (4%) | SIFT tolerated (0.62); PolyPhen benign (0.096); catalogued as COSV61551783; called by muse, mutect2
- ASIC1 | c.572A>G p.Y191C | Missense Mutation (SNP) | VAF 45/1162 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- CISH | c.73C>T p.P25S (on ENST00000348721 / NM_145071.4; = p.P42S on NM_013324.6) | Missense Mutation (SNP) | VAF 25/731 reads (3%) | SIFT tolerated (0.76); PolyPhen benign (0.001); called by muse, mutect2
- CSMD2 | c.9062G>A p.G3021E | Missense Mutation (SNP) | VAF 54/1064 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- EIF2AK2 | c.1183T>C p.F395L | Missense Mutation (SNP) | VAF 304/980 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- NPDC1 | c.387C>A p.A129= | Splice Region (SNP) | VAF 48/922 reads (5%) | called by muse, mutect2
- SCARA5 | c.452G>A p.G151D | Missense Mutation (SNP) | VAF 29/826 reads (4%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.554); called by muse, mutect2
- ZNF268 | c.382G>A p.D128N | Missense Mutation (SNP) | VAF 53/481 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- COLEC12 | c.528C>T p.G176= | Silent (SNP) | VAF 29/743 reads (4%) | called by muse, mutect2
- IQCG | c.556T>C p.L186= | Silent (SNP) | VAF 24/902 reads (3%) | called by muse, mutect2
- AP1B1 | c.2767-53T>A | Intron (SNP) | VAF 8/116 reads (7%) | called by muse, mutect2
- C22orf15 | c.435+36G>A | Intron (SNP) | VAF 28/287 reads (10%) | called by muse, mutect2
- EDA2R | c.518-193A>G | Intron (SNP) | VAF 19/617 reads (3%) | called by muse, mutect2
- TRPC7 | c.2041-57G>A | Intron (SNP) | VAF 24/388 reads (6%) | catalogued as rs921876832; called by muse, mutect2
- ZNF451 | c.2609-43G>A | Intron (SNP) | VAF 11/278 reads (4%) | called by muse, mutect2
